Gene-level copy-number profile of specimen HCM-SANG-1305-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-1305-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-1305-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4f091747-4050-477c-a130-d782b88ac62c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1305-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/0900ecbe-33e4-4a94-b127-2d1c86269c19

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,432; copy number 2: 32,168; copy number 3: 16,864; copy number 4: 2,052; copy number 5: 3,075; copy number 6: 80; copy number 7: 26; copy number 8: 39; copy number 9: 92; copy number 11: 75.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,143,458–4,150,421, 1 gene: UNC93B4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,387 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–144,474,790, 39 genes, copy number 8: AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1.
- chr1:149,903,318–153,785,821, 215 genes, copy number 5 (broad region; genes not listed).
- chr1:153,793,947–153,802,091, 1 gene, copy number 5: AL513523.2.
- chr2:170,640,374–197,786,762, 395 genes, copy number 5–6 (within-gene range 3–7) (broad region; genes not listed).
- chr3:166,160,021–171,460,408, 92 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:193,740,471–198,123,232, 157 genes, copy number 5 (broad region; genes not listed).
- chr6:41,189,749–47,477,572, 167 genes, copy number 9–11 (broad region; genes not listed).
- chr6:69,866,556–71,652,611, 34 genes, copy number 5: COL19A1, RPL37P15, COL9A1, AL160262.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.1, KRT19P1, RNU4-66P.
- chr8:39,314,591–39,522,852, 2 genes, copy number 5: ADAM5, ADAM3A.
- chr8:62,110,524–145,066,685, 1,263 genes, copy number 5 (broad region; genes not listed).
- chr10:47,908,064–47,999,791, 4 genes, copy number 5: AC245041.2, NPY4R2, AC245041.1, FAM25C.
- chr19:29,901,696–30,957,192, 15 genes, copy number 5: AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr20:6,731,080–16,053,197, 89 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr20:14,884,250–14,929,528, 1 gene, copy number 5 (within-gene range 1–5): MACROD2-AS1.
- chr20:15,552,157–16,983,033, 16 genes, copy number 5: AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1, U3.
- chr20:30,278,906–64,327,972, 869 genes, copy number 5 (broad region; genes not listed).
- chr21:7,744,962–8,680,934, 28 genes, copy number 6–7: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.

Autosomal genes at a single copy (total copy number 1): 3,230. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
